Somatic mutation profile of tumor specimen TCGA-EM-A1CV-01A (aliquot TCGA-EM-A1CV-01A-11D-A13W-08) from TCGA case TCGA-EM-A1CV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.7 years (11,932 days).
Specimen TCGA-EM-A1CV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78820a8e-aea1-4d2e-966d-81915ce9e8e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1CV-10A (Blood Derived Normal), aliquot TCGA-EM-A1CV-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e20f77c-f3e7-4125-a2c7-527d66ddc5e7

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 5, Silent 5, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNAL1 | c.1942-2A>T p.X648_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | catalogued as COSV57701388; called by muse, mutect2, varscan2
- EXOC2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57861176; called by muse, mutect2, varscan2
- KANK4 | c.2464C>T p.H822Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1456938380, COSV100443292; called by mutect2, varscan2
- NCR1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs756166596, COSV52555430; called by muse, mutect2, varscan2
- PTCHD3 | c.1816G>T p.V606F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71256304; called by muse, mutect2, varscan2
- SVOPL | c.1353+1del p.X451_splice (on ENST00000419765; = p.X299_splice on NM_174959.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 6/21 reads (29%) | catalogued as COSV99939149; called by mutect2, pindel, varscan2
- ADGRG4 | c.4626A>C p.T1542= | Silent (SNP) | VAF 5/134 reads (4%) | catalogued as COSV54949956, COSV54965611; called by muse, mutect2
- CHRND | c.261G>A p.R87= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- SP140 | c.912T>A p.T304= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV59446444; called by muse, mutect2, varscan2
- SUFU | c.660G>A p.L220= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV64013920; called by muse, mutect2
- USP9X | c.5319A>G p.K1773= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV61066188; called by muse, mutect2, varscan2
